Gene-level copy-number profile of tumor specimen TCGA-09-0367-01A from TCGA case TCGA-09-0367, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.0 years (24,473 days).
Specimen TCGA-09-0367-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.41399846-fdce-43f6-80fa-25f214c43933.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-0367-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6ebf403b-77f0-4ce1-b7dd-b174f17a249b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,138; copy number 2: 7,303; copy number 3: 17,690; copy number 4: 18,312; copy number 5: 7,952; copy number 6: 3,624; copy number 7: 1,637; copy number 8: 793; copy number 9: 271; copy number 11: 68; copy number 12: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-09-0367-01): tumor purity 0.72, ploidy 6.18, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 357 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–11,466,177, 193 genes, copy number 9–11 (broad region; genes not listed).
- chr8:105,546,089–106,060,524, 1 gene, copy number 12 (within-gene range 8–12): ZFPM2-AS1.
- chr8:105,737,280–119,325,265, 108 genes, copy number 9–12 (broad region; genes not listed).
- chr10:24,816,331–27,414,368, 55 genes, copy number 9: AL157385.2, PRTFDC1, AL157385.1, RN7SKP241, AL512598.2, AL512598.1, ENKUR, THNSL1, LINC01516, GPR158-AS1, GPR158, AL354976.1, RN7SKP220, GPN3P1, LINC00836, HIRAP1, RNA5SP306, RNU6-632P, AL358612.1, MYO3A, GAD2, AL355798.1, APBB1IP, RNA5SP307, AL160287.1, FAM238A, AL390961.1, FAM238B, SELENOOLP, AL390961.3, PDSS1, HSPA8P3, AL390961.2, ABI1, AL139404.1, RNU6-946P, FAM238C, ANKRD26, RNU6-490P, YME1L1, MASTL, ACBD5, RNU2-24P, RNU7-12P, AL160291.1, LRRC37A6P, ARMC4P1, AL355493.6, RNU6-666P, AL355493.1, RNU6-452P, LINC02673, FAM210CP, TRIAP1P1, PTCHD3.

Autosomal genes at a single copy (total copy number 1): 554. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
